Gene-level copy-number profile of tumor specimen ALCH-B1VE-TTR1-A from ALCHEMIST case ALCH-B1VE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 65.9 years (24,076 days).
Specimen ALCH-B1VE-TTR1-A: Sample type: FFPE Recurrent; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5391aa4f-e954-4647-9da7-adefb4887787.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1VE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,245 have no estimate.
https://portal.gdc.cancer.gov/files/6fe8323f-73e4-4008-a644-37d5c10423b3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 31; copy number 1: 21,013; copy number 2: 29,774; copy number 3: 5,782; copy number 4: 985; copy number 5: 48; copy number 6: 365; copy number 7: 211; copy number 8: 1; copy number 9: 109; copy number 10: 11; copy number 11: 3; copy number 15: 1; copy number 21: 26; copy number 34: 1; copy number 40: 8; copy number 51: 1; copy number 89: 8.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:25,697,076–25,697,188, 1 gene: Y_RNA.
- chr3:46,742,092–46,750,891, 1 gene (within-gene range 0–1): PRSS45P.
- chr3:46,753,045–46,798,390, 2 genes (within-gene range 0–1): PRSS43P, AC109583.2.
- chr10:111,104,956–112,356,574, 10 genes: AL355863.1, BTBD7P2, AC021035.1, RPS6P15, AL136119.1, GPAM, TECTB, MIR6715B, MIR6715A, GUCY2GP.
- chr11:66,546,395–66,568,879, 3 genes: ACTN3, AP002748.2, CTSF.
- chr15:25,189,414–25,191,497, 2 genes (within-gene range 0–2): SNORD115-11, SNORD115-12.
- chr15:25,197,576–25,211,877, 9 genes (within-gene range 0–2): SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23.
- chr15:25,250,859–25,250,940, 1 gene (within-gene range 0–2): SNORD115-44.
- chr17:12,549,764–12,642,854, 2 genes: LINC00670, AC068442.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 793 genes in 19 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,720,510–155,660,245, 541 genes, copy number 6–9 (within-gene range 3–9) (broad region; genes not listed).
- chr2:2,729,908–2,730,957, 1 gene, copy number 7: AC018685.1.
- chr5:10,195,121–12,297,504, 36 genes, copy number 5: AC034229.2, AC034229.3, AC034229.4, ATPSCKMT, AC012640.1, CCT5, AC012640.4, AC012640.3, CMBL, Y_RNA, Y_RNA, AC012640.5, AC012640.2, MARCHF6, ROPN1L-AS1, ROPN1L, MIR6131, LINC01513, RPL30P7, AC092336.1, LINC02212, LINC02213, AC112200.2, AC112200.1, ANKRD33B, ANKRD33B-AS1, AC106760.1, AC106760.2, AC012629.4, AC012629.3, DAP, AC012629.2, AC012629.1, CTNND2, RNU6-429P, RNU6-679P.
- chr6:32,517,353–32,530,287, 1 gene, copy number 6: HLA-DRB5.
- chr7:54,542,325–56,000,181, 41 genes, copy number 9–89: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2, VOPP1, AC099681.1, AC099681.3, AC099681.2, CDC42P2, TUBBP6, AC091812.1, FKBP9P1, RNU6-389P, Metazoa_SRP, SUMO2P3, CICP11, AC091812.3, AC091812.2, PSPHP1, RNU6-1126P, SEPTIN14, AC092647.4, CICP12, AC092647.3, AC092647.1, AC092647.2, AC092647.5, ZNF713, NIPSNAP2, MRPS17.
- chr7:56,163,145–57,837,046, 89 genes, copy number 6 (broad region; genes not listed).
- chr10:42,149,310–43,267,065, 34 genes, copy number 5–6: KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8, BX322639.1, CCNYL2, AL391099.1, LINC00839, ZNF37BP, FXYD6P1, EIF3LP2, ZNF33B, AL022345.3, AL022345.1, AL022345.2, RNU6-1170P, AL022345.4, LINC01518, VN1R54P, CUBNP1, LINC02632, RSU1P1, DUXAP3, AL022344.1, BMS1, RNU6-885P, LINC02623, LINC01264, MIR5100, RET, AC010864.1, CSGALNACT2, RASGEF1A.
- chr10:54,486,230–54,656,051, 3 genes, copy number 5 (within-gene range 2–5): AL353784.1, NEFMP1, MIR548F1.
- chr14:105,583,731–105,588,395, 1 gene, copy number 6: IGHA2.
- chr14:105,620,506–105,626,066, 1 gene, copy number 15 (within-gene range 1–15): IGHG4.
- chr15:21,293,653–21,946,641, 30 genes, copy number 5–21: AC068446.1, AC068446.2, RNU6-1235P, POTEB3, MIR3118-3, U6, NF1P9, MIR5701-2, AC183088.4, AC183088.2, AC183088.1, LINC02203, AC183088.3, AC135068.6, AC135068.2, AC135068.12, AC135068.11, AC135068.1, AC135068.4, AC135068.5, AC135068.8, AC135068.7, AC135068.9, AC135068.10, AC135068.3, AC134981.1, MIR3118-4, POTEB, RNU6-631P, NF1P2.
- chr16:1,349,240–1,351,878, 1 gene, copy number 10 (within-gene range 3–10): TSR3.
- chr16:32,356,981–32,380,049, 2 genes, copy number 9: AC133548.1, ACTR3BP3.
- chr21:43,092,956–43,107,570, 1 gene, copy number 5: U2AF1.
- chr21:43,115,334–43,141,092, 2 genes, copy number 5–7: MRPL51P2, FRGCA.
- chr21:43,169,008–43,172,805, 1 gene, copy number 9: CRYAA.
- chr21:43,414,483–43,479,534, 4 genes, copy number 8–34: SIK1, LINC00319, LINC00313, AP001048.1.
- chr21:44,107,373–44,210,114, 2 genes, copy number 6–51 (within-gene range 2–51): PWP2, GATD3A.
- chr21:44,172,169–44,194,338, 2 genes, copy number 7: AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 20,147. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
